Somatic mutation profile of tumor specimen 0DHMSD from CCDI case PBBUNU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.4 years (4,158 days).
Specimen 0DHMSD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6375716b-7844-4a80-ba9b-ffe97c98bce2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHMLU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cef3bed-2dfd-4bbc-bb6e-dc24af626212

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'UTR 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC168 | c.10571A>G p.Q3524R | Missense Mutation (SNP) | VAF 330/852 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.006); called by muse, varscan2
- LCTL | c.1345A>T p.I449L | Missense Mutation (SNP) | VAF 78/506 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.056); called by muse, varscan2
- TBC1D4 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 264/616 reads (43%) | called by muse, varscan2
- DCHS1 | c.4647G>T p.P1549= | Silent (SNP) | VAF 177/420 reads (42%) | catalogued as COSV55036037; called by muse, varscan2
- GPRIN3 | c.*36C>T | 3'UTR (SNP) | VAF 44/366 reads (12%) | catalogued as rs773581472, COSV100310649; called by muse, varscan2
